Gene-level copy-number profile of tumor specimen TCGA-55-6972-01A from TCGA case TCGA-55-6972, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.9 years (26,625 days).
Specimen TCGA-55-6972-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4a90a4e2-8a23-425d-a249-5bce63edf3cb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6972-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60a9b1db-a8ed-4862-9c2a-33588820fb0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 187; copy number 2: 13,717; copy number 3: 17,707; copy number 4: 16,084; copy number 5: 8,208; copy number 6: 1,892; copy number 7: 1,941; copy number 8: 4; copy number 10: 79.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6972-01A-11D-1943-01): tumor purity 0.83, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,024 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–200,177,420, 1,471 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:236,348,257–248,919,946, 287 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:58,198–6,030,841, 120 genes, copy number 7–10 (broad region; genes not listed).
- chr5:7,830,378–8,898,052, 31 genes, copy number 7: C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199.
- chr5:14,581,792–14,992,961, 15 genes, copy number 7: OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2.
- chr5:19,471,296–20,575,873, 4 genes, copy number 8 (within-gene range 5–8): CDH18, AC093303.1, AC094103.1, CDH18-AS1.
- chr5:35,429,064–40,984,643, 96 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
